FM case AD7847 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/ea65d01b-ab96-409d-b1ef-e5f4734ddd7f

Male, 61.8 years: Glioblastoma (ICD-O-3 9440/3) of the nervous system; metastasis biopsied or resected from the brain. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
